Gene-level copy-number profile of tumor specimen TCGA-05-4434-01A from TCGA case TCGA-05-4434, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 67.0 years (24,472 days).
Specimen TCGA-05-4434-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.1ea05561-a049-49c8-8a1a-fbd92296ac29.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-05-4434-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/85533476-fb7a-456c-9e14-3923b3b0ae6f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 133; copy number 2: 3,563; copy number 3: 6,763; copy number 4: 39,976; copy number 5: 6,630; copy number 6: 1,588; copy number 7: 301; copy number 8: 181; copy number 9: 140; copy number 10: 127; copy number 11: 103; copy number 12: 55; copy number 13: 118; copy number 14: 126; copy number 15: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-05-4434-01A-01D-1204-01): tumor purity 0.45, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 625 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:121,079,494–122,211,811, 16 genes, copy number 10: TBC1D32, RNU6-1286P, Y_RNA, AL139098.1, AL139098.2, GJA1, RNU4-35P, AL138729.1, RNU4-76P, RNU2-8P, AL603865.2, SLC25A5P7, RPL23AP48, AL603865.1, HMGB3P18, RNU1-18P.
- chr6:123,589,711–124,825,640, 3 genes, copy number 10 (within-gene range 5–10): AL133257.1, NKAIN2, AL354936.1.
- chr6:135,283,532–135,497,765, 1 gene, copy number 14 (within-gene range 6–14): AHI1.
- chr6:135,474,504–139,667,284, 78 genes, copy number 14 (within-gene range 6–14) (broad region; genes not listed).
- chr6:139,938,864–141,404,494, 11 genes, copy number 15: AL050338.2, AL357146.1, RNA5SP220, MIR3668, AL035446.2, MIR4465, RPS3AP24, AL035446.1, AL357084.1, AL357080.1, AL355596.2.
- chr8:75,302,296–78,956,082, 30 genes, copy number 9: HIGD1AP6, PKMP4, HNF4G, AC011029.1, RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18, AC062004.1, AC084706.1, PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, AC068700.2, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605.
- chr8:80,585,585–83,408,900, 48 genes, copy number 10: RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, AC012533.1, PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5, AC018616.1, PMP2, FABP9, FABP4, AC023644.1, FTH1P11, FABP12, IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1, IMPA1, SLC10A5, AC132219.2, ZFAND1, CHMP4C, AC132219.1, SNX16, HNRNPA1P36, LINC02235, AC060765.2, LINC02839, HNRNPA1P4, AC060765.1, AC105031.2, AC105031.1, AC090095.1, AC090132.1, AC090132.2, LINC01419.
- chr8:100,133,351–102,688,906, 74 genes, copy number 11 (within-gene range 4–11) (broad region; genes not listed).
- chr8:104,590,733–105,804,539, 1 gene, copy number 11 (within-gene range 4–11): ZFPM2.
- chr8:104,981,164–113,436,939, 75 genes, copy number 11–14 (within-gene range 8–14) (broad region; genes not listed).
- chr8:115,408,496–115,809,673, 1 gene, copy number 10 (within-gene range 8–10): TRPS1.
- chr8:115,950,511–137,698,467, 287 genes, copy number 9–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 133. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
